Gene-level copy-number profile of tumor specimen CDDP-ACR2-TTP1-A from CDDP_EAGLE case CDDP-ACR2, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79 years.
Specimen CDDP-ACR2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4994fcb4-546e-41d9-994c-bd16c6e59278.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACR2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/62c2cea3-5d46-4034-91f6-bb651fa92b7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,213; copy number 2: 53,516; copy number 3: 3,612; copy number 4: 39; copy number 5: 1; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:20,501,513–20,512,357, 2 genes, copy number 6: KRT16P3, AC015818.7.
- chr17:46,503,946–46,555,650, 2 genes, copy number 5–6 (within-gene range 3–6): RDM1P2, LRRC37A2.
- chr17:46,537,534–46,537,814, 1 gene, copy number 6 (within-gene range 3–6): RN7SL199P.

Autosomal genes at a single copy (total copy number 1): 923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
